Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9KE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9KE-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site (R) Kidney NOS C64.9
JW 6/13/14

I: Slide of a nephrectomy with a poorly differentiated papillary Renal Cell Carcinoma (type 2) with subtotal necrotic features, bleeding, and cholesterol crystal build up. Tumor is encapsulated but with protrusions into the perirenal fat layer. Ureter and surgical margins are tumor free.

Classification pTNM 2010:

Stage: pT1b L0 V0 Pn0

Grade: G3 (Fuhrmann-Grad 3)

R-Classification: Local R0

ICD-O: 8260/3.

Laterality = (R)

Source: NCI Genomic Data Commons file 8068ff1f-5d22-4892-8042-f17497e2a5c1 (TCGA-5P-A9KE.ED6A0F15-05FD-4062-B508-91BF1019B6D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).